Somatic mutation profile of tumor specimen TARGET-30-PALTEG-01A (aliquot TARGET-30-PALTEG-01A-01W) from TARGET case TARGET-30-PALTEG, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 3.7 years (1,367 days).
Specimen TARGET-30-PALTEG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f13f59d-e06f-48cf-b8a3-763f8e34d93b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALTEG-10A (Blood Derived Normal), aliquot TARGET-30-PALTEG-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89939bfe-da94-4b50-8f3b-cd7354b1c8f6

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 16, Silent 7, Nonsense Mutation 5, Splice Site 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CR2 | c.2120G>A p.W707* | Nonsense Mutation (SNP) | VAF 43/292 reads (15%) | catalogued as rs398122863, COSV65508816; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BPIFB2 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 52/243 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs930579273, COSV50063479, COSV50064657; called by muse, mutect2, varscan2
- C4orf17 | c.1046A>G p.Q349R | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as COSV56745069; called by muse, mutect2, varscan2
- CEP192 | c.6951+2T>G p.X2317_splice | Splice Site (SNP) | VAF 52/317 reads (16%) | catalogued as rs1439565455, COSV58064778; called by muse, mutect2, varscan2
- EFTUD2 | c.2135A>G p.K712R | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.33); catalogued as COSV53655674; called by muse, mutect2, varscan2
- FCRL1 | c.310A>C p.N104H | Missense Mutation (SNP) | VAF 71/296 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV63825349; called by muse, mutect2, varscan2
- FMO2 | c.183C>G p.N61K | Missense Mutation (SNP) | VAF 49/321 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV52947921; called by muse, mutect2, varscan2
- HELB | c.1823G>T p.C608F | Missense Mutation (SNP) | VAF 48/347 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as COSV56073945; called by muse, mutect2, varscan2
- KRT10 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 126/1184 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.183); catalogued as rs373319671; called by muse, varscan2
- LILRB1 | c.1800+1G>T p.X600_splice (on ENST00000427581; = p.X550_splice on NM_006669.6) | Splice Site (SNP) | VAF 24/213 reads (11%) | catalogued as COSV61118460; called by muse, mutect2, varscan2
- LY75 | c.4191G>T p.Q1397H | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV55106103; called by muse, mutect2, varscan2
- MAP3K12 | c.2380C>T p.Q794* | Nonsense Mutation (SNP) | VAF 32/178 reads (18%) | catalogued as COSV57233014; called by muse, mutect2, varscan2
- MYO1D | c.2603G>A p.R868Q | Missense Mutation (SNP) | VAF 55/581 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs565039949, COSV100554746; called by muse, mutect2
- OR10X1 | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 46/260 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV63767403; called by muse, mutect2, varscan2
- RLF | c.3140C>T p.S1047F | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV65651975; called by muse, mutect2, varscan2
- RREB1 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 67/245 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV58558556; called by muse, mutect2, varscan2
- SCIN | c.1624G>C p.V542L (on ENST00000297029 / NM_001112706.3; = p.V295L on NM_033128.3) | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.082); catalogued as COSV51693125; called by muse, mutect2, varscan2
- SEPTIN4 | c.1007C>G p.T336S | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV58727996; called by muse, mutect2, varscan2
- SERPINI1 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 27/207 reads (13%) | catalogued as COSV55511041; called by muse, varscan2
- TEX101 | c.179G>T p.C60F (on ENST00000598265 / NM_001130011.3; = p.C78F on NM_031451.4) | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53661971; called by muse, mutect2, varscan2
- ZNF804B | c.2723C>G p.S908* | Nonsense Mutation (SNP) | VAF 139/1300 reads (11%) | catalogued as COSV60829438; called by muse, mutect2
- ABCA13 | c.1646C>A p.S549* | Nonsense Mutation (SNP) | VAF 16/194 reads (8%) | called by muse, mutect2
- FZD2 | c.134C>A p.P45Q | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2
- GPR149 | c.981+2T>C p.X327_splice | Splice Site (SNP) | VAF 24/589 reads (4%) | called by muse, mutect2
- KMT2C | c.2468_2481del p.I823Tfs*5 | Frame Shift Del (DEL) | VAF 159/922 reads (17%) | called by pindel, varscan2
- HECTD4 | c.11421A>G p.P3807= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV66392552; called by muse, mutect2
- HPS3 | c.2262T>A p.I754= | Silent (SNP) | VAF 41/206 reads (20%) | catalogued as COSV56054623; called by muse, mutect2, varscan2
- KDM3B | c.2493G>A p.K831= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as COSV58690986; called by muse, mutect2, varscan2
- NUP210L | c.4812T>A p.I1604= | Silent (SNP) | VAF 25/169 reads (15%) | catalogued as COSV55148353; called by muse, mutect2, varscan2
- PRKAA2 | c.1050T>G p.S350= | Silent (SNP) | VAF 48/202 reads (24%) | catalogued as COSV64803959; called by muse, mutect2, varscan2
- QRICH2 | c.264A>T p.S88= | Silent (SNP) | VAF 12/232 reads (5%) | called by muse, mutect2
- USP6 | c.1065C>T p.D355= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as COSV51483508; called by muse, mutect2
